Somatic mutation profile of tumor specimen BA3103D (aliquot aq-BA3103D) from BEATAML1.0 case 2790, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, CBF-beta/MYH11; Tissue or organ of origin: Bone marrow; Age at diagnosis: 49.7 years (18,168 days).
Specimen BA3103D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 112a0b29-b66d-45f1-9952-4fc2231a4f37.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA3267D (Solid Tissue Normal), aliquot aq-BA3267D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/312613bc-967f-4276-9f68-28c08505f4b5

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, In Frame Del 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIT | c.1248_1255delinsAT p.T417_D419delinsY | In Frame Del (DEL) | VAF 9/110 reads (8%) | catalogued as COSV55395053, COSV55399723, COSV55422105; called by pindel, varscan2*
- RASAL2 | c.865C>T p.R289C | Missense Mutation (SNP) | VAF 20/236 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200438546; called by muse, mutect2
- CGN | c.2272G>A p.A758T | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0.272); called by muse, mutect2
- TDRD6 | c.5268A>G p.K1756= | Silent (SNP) | VAF 13/216 reads (6%) | called by muse, mutect2
